Gene-level copy-number profile of tumor specimen TCGA-S6-A8JX-01A from TCGA case TCGA-S6-A8JX, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 27.3 years (9,963 days).
Specimen TCGA-S6-A8JX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.f76cf8d2-97f4-4b0d-a607-4127ce2c9528.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-S6-A8JX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c8c95200-f04d-40c3-a2c1-b6b8c0428580

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,158; copy number 2: 14,166; copy number 3: 28,945; copy number 4: 11,540; copy number 5: 2,381; copy number 6: 792; copy number 8: 345; copy number 17: 493.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-S6-A8JX-01A-11D-A434-01): tumor purity 0.89, ploidy 3.09, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 838 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:66,767–33,718,217, 838 genes, copy number 8–17 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,155. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
